Somatic mutation profile of tumor specimen TCGA-DX-A48N-01A (aliquot TCGA-DX-A48N-01A-11D-A307-09) from TCGA case TCGA-DX-A48N, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 47.5 years (17,364 days).
Specimen TCGA-DX-A48N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60ba7c58-1706-45aa-b604-1637de41df4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A48N-10A (Blood Derived Normal), aliquot TCGA-DX-A48N-10A-01D-A307-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b8fadce-7e79-426a-86ad-52a7206ff5b4

The open-access MAF lists 32 somatic variants for this specimen: 25 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 19, Silent 7, Frame Shift Del 2, Splice Site 2, Nonstop Mutation 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACLY | c.599T>G p.L200R | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100709929; called by muse, mutect2, varscan2
- ADGRV1 | c.11980G>C p.E3994Q | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.174); catalogued as COSV101316627; called by muse, mutect2, varscan2
- CASZ1 | c.1133T>A p.V378D | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV100681024, COSV100682248; called by muse, mutect2, varscan2
- CHD5 | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV52408358, COSV99315280; called by muse, mutect2, varscan2
- CHSY3 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100520088; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1787C>G p.S596C (on ENST00000361735 / NM_015935.5; = p.S510C on NM_014955.3) | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.421); catalogued as rs1484318829, COSV100676063; called by muse, mutect2
- GABRG1 | c.367del p.R123Vfs*2 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | catalogued as COSV99778822; called by mutect2, pindel, varscan2
- GPR143 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1186621212, COSV101102319; called by muse, mutect2, varscan2
- HMMR | c.146-1G>C p.X49_splice | Splice Site (SNP) | VAF 13/81 reads (16%) | catalogued as COSV100243731, COSV57085555; called by muse, mutect2, varscan2
- HRH3 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746260159, COSV100420746; called by muse, mutect2, varscan2
- KIAA1958 | c.1784T>C p.F595S | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as COSV100516530; called by muse, mutect2
- KLHL32 | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100987514; called by muse, mutect2
- KRTAP5-5 | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.793); catalogued as COSV101294225, COSV68784867; called by muse, mutect2, varscan2
- LIPI | c.1412T>C p.L471P | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100754048; called by muse, mutect2, varscan2
- METTL25 | c.1811G>C p.*604Sext*13 | Nonstop Mutation (SNP) | VAF 204/530 reads (38%) | catalogued as COSV99942741; called by muse, mutect2, varscan2
- MUC16 | c.3027G>T p.M1009I | Missense Mutation (SNP) | VAF 24/331 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as COSV101201917; called by muse, mutect2
- NOS1 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs913433943, COSV57609864; called by muse, mutect2
- OR1D2 | c.259T>C p.S87P | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV100514019; called by muse, mutect2
- PDE6B | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.569); catalogued as rs751477149, COSV99728521; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIK3AP1 | c.2171-2A>T p.X724_splice | Splice Site (SNP) | VAF 14/56 reads (25%) | catalogued as COSV100226271; called by muse, mutect2, varscan2
- TGFB1 | c.595G>C p.D199H | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV55723811, COSV99700311; called by muse, mutect2, varscan2
- TLR6 | c.244A>G p.R82G | Missense Mutation (SNP) | VAF 13/290 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as COSV101126317; called by muse, mutect2
- ZNF611 | c.1679A>C p.H560P | Missense Mutation (SNP) | VAF 65/134 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753938122, COSV100160670; called by muse, mutect2, varscan2
- SLC11A1 | c.409_412del p.L137Gfs*2 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, varscan2
- TRAPPC2L | c.-37_4del | Translation Start Site (DEL) | VAF 16/34 reads (47%) | called by mutect2, pindel
- ANO7 | c.1149A>G p.E383= (on ENST00000274979; = p.E329= on NM_001370694.2) | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as COSV99239579; called by muse, mutect2, varscan2
- APBA2 | c.321C>T p.D107= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as rs369962967; called by muse, mutect2, varscan2
- HSPG2 | c.2652C>T p.S884= | Silent (SNP) | VAF 41/78 reads (53%) | catalogued as COSV65974318; called by muse, mutect2, varscan2
- RIN1 | c.1542G>T p.R514= | Silent (SNP) | VAF 41/99 reads (41%) | catalogued as COSV100255027; called by muse, mutect2, varscan2
- SERPINA6 | c.1002C>T p.I334= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as COSV100448504; called by muse, mutect2, varscan2
- SPTBN5 | c.7617G>A p.A2539= | Silent (SNP) | VAF 37/74 reads (50%) | catalogued as rs766802057, COSV58028034; called by muse, mutect2, varscan2
- TMTC4 | c.1977A>G p.A659= (on ENST00000376234 / NM_001350577.2; = p.A678= on NM_032813.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 41/73 reads (56%) | catalogued as COSV100168936; called by muse, mutect2, varscan2
